Somatic mutation profile of tumor specimen TCGA-EE-A3AA-06A (aliquot TCGA-EE-A3AA-06A-11D-A196-08) from TCGA case TCGA-EE-A3AA, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 47.1 years (17,196 days).
Specimen TCGA-EE-A3AA-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f3b87151-4ae0-4193-aa2b-d15f4d53ce44.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A3AA-10A (Blood Derived Normal), aliquot TCGA-EE-A3AA-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d5862c58-9c99-415e-979f-33190f55a774

The open-access MAF lists 1,448 somatic variants for this specimen: 919 protein-altering or splice-affecting, 506 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 859, Silent 506, Nonsense Mutation 29, Splice Region 16, Intron 12, Splice Site 11, RNA 6, 3'UTR 4, Frame Shift Del 2, Frame Shift Ins 1, Translation Start Site 1, 5'Flank 1.

Variants (750 of 1,448; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP7B | c.3517G>A p.E1173K | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs756029120, CM993112, COSV54436876; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- BCORL1 | c.2648G>A p.G883E | Missense Mutation (SNP) | VAF 6/20 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs138477961, COSV99499928; called by muse, varscan2
- BRAF | c.1921A>G p.K641E (on ENST00000288602 / NM_001374244.1; = p.K601E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as rs121913364, CM092083, COSV56058494; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CHST14 | c.958C>T p.R320* | Nonsense Mutation (SNP) | VAF 6/57 reads (11%) | catalogued as rs1555410784, COSV100086993; ClinVar: likely pathogenic; called by mutect2, varscan2
- DICER1 | c.745C>T p.Q249* | Nonsense Mutation (SNP) | VAF 22/186 reads (12%) | catalogued as rs886037732, COSV58617444, COSV58631087; ClinVar: pathogenic; called by mutect2, varscan2
- GABRG2 | c.1456C>T p.R486W (on ENST00000361925 / NM_001375343.1; = p.R446W on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs796052515, COSV62716724, COSV62717465; ClinVar: pathogenic / uncertain significance; called by mutect2, varscan2
- GJA8 | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs864309677, CM162283, COSV53788425; ClinVar: likely pathogenic; called by muse, varscan2
- HNF4A | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs1555813319, CM111488, COSV57385421; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- KRT83 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs57802288, CM050656, COSV53339266; ClinVar: likely pathogenic / not provided; called by mutect2, varscan2
- TP53 | c.452C>T p.P151L | Missense Mutation (SNP) | VAF 5/33 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.757); catalogued as COSV52677206, COSV52707835, COSV52811105; called by mutect2, varscan2
- TP53 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 6/32 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as rs28934874, CM012662, CM120847, CM941326, COSV52661698, COSV52676321, COSV52676982, COSV52701855; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- UCHL1 | c.481C>T p.H161Y | Missense Mutation (SNP) | VAF 18/166 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52651371; called by muse, varscan2
- ABCA12 | c.5467C>T p.L1823= (on ENST00000272895 / NM_173076.3; = p.L1505= on NM_015657.3) | Splice Region (SNP) | VAF 16/126 reads (13%) | catalogued as COSV55954018; called by muse, mutect2, varscan2
- ABCA4 | c.5915G>A p.G1972E | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100933161, COSV64672488; called by muse, mutect2, varscan2
- ABCA4 | c.5887C>T p.R1963C | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); catalogued as rs777887467, COSV64671225; called by mutect2, varscan2
- ABCB5 | c.1939C>T p.P647S (on ENST00000404938 / NM_001163941.2; = p.P202S on NM_178559.6) | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as COSV51706555; called by muse, mutect2, varscan2
- ABCB7 | c.422C>T p.A141V (on ENST00000373394 / NM_001271696.3; = p.A142V on NM_004299.6) | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV53723792; called by muse, mutect2
- ABCC6 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.905); catalogued as COSV52742735; called by muse, mutect2, varscan2
- ABCC8 | c.3912G>A p.M1304I | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs1243802291, COSV56848248; called by muse, varscan2
- ABCC8 | c.548T>A p.L183H | Missense Mutation (SNP) | VAF 26/270 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV56848269; called by muse, varscan2
- ABCC9 | c.3302A>G p.N1101S | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.574); catalogued as COSV53966691; called by muse, mutect2, varscan2
- ABCD2 | c.2004-1G>A p.X668_splice | Splice Site (SNP) | VAF 7/54 reads (13%) | catalogued as COSV100429581; called by muse, mutect2
- ABL2 | c.1460C>T p.P487L (on ENST00000502732 / NM_007314.4; = p.P472L on NM_005158.5) | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61012313; called by muse, varscan2
- ABRAXAS2 | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV53716491; called by mutect2, varscan2
- ACAN | c.5927G>A p.G1976E | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1382814393, COSV61358417, COSV61369586; called by muse, mutect2, varscan2
- ACTL7B | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.137); catalogued as rs909538683, COSV65927126; called by muse, varscan2
- ADAM29 | c.2087G>A p.R696Q | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.046); catalogued as rs748743733, COSV63659968; called by mutect2, varscan2
- ADAM30 | c.307C>T p.H103Y | Missense Mutation (SNP) | VAF 69/414 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as rs765610008, COSV65560702; called by mutect2, varscan2
- ADAMTS18 | c.2332G>A p.E778K | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.322); catalogued as rs779170683, COSV51399738; called by mutect2, varscan2
- ADAMTS18 | c.1058G>A p.G353E | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV51403092; called by muse, varscan2
- ADAMTS19 | c.2534T>A p.I845N | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV50738697; called by muse, varscan2
- ADAMTS6 | c.2902T>G p.W968G | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100068446; called by muse, mutect2, varscan2
- ADCY10 | c.3594-1G>A p.X1198_splice | Splice Site (SNP) | VAF 21/74 reads (28%) | catalogued as COSV63239487; called by muse, mutect2, varscan2
- ADD2 | c.740C>T p.S247F | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52457824; called by mutect2, varscan2
- ADGRA1 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.263); catalogued as rs374491629; called by mutect2, varscan2
- ADGRA3 | c.2654C>T p.P885L | Missense Mutation (SNP) | VAF 10/197 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51560486, COSV51561706; called by muse, mutect2
- ADGRG4 | c.7795C>G p.P2599A | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.124); catalogued as COSV54952757; called by muse, mutect2, varscan2
- ADGRV1 | c.16900C>T p.Q5634* | Nonsense Mutation (SNP) | VAF 8/42 reads (19%) | catalogued as COSV67982168; called by mutect2, varscan2
- ADH1A | c.134G>A p.G45E | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52924612; called by muse, mutect2, varscan2
- ADRA2B | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs1440203097, COSV69787326; called by muse, mutect2, varscan2
- ADRB2 | c.932T>G p.L311R | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60005325; called by muse, mutect2, varscan2
- AGFG2 | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.051); catalogued as COSV53544587; called by muse, mutect2, varscan2
- AHCTF1 | c.151C>T p.P51S (on ENST00000366508; = p.P25S on NM_015446.5) | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV58248001; called by mutect2, varscan2
- AKAP1 | c.1660G>A p.D554N | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.418); catalogued as COSV58469339; called by muse, mutect2, varscan2
- AKAP3 | c.981A>C p.K327N | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV57415381; called by muse, mutect2, varscan2
- AL121899.2 | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.869); catalogued as COSV67350146; called by muse, varscan2
- AL645922.1 | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 39/179 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.832); catalogued as rs568459262, COSV54960045; called by muse, mutect2, varscan2
- ALG1 | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.055); catalogued as COSV52156797; called by muse, varscan2
- ALK | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV66563160; called by muse, mutect2, varscan2
- ALMS1 | c.10597C>T p.Q3533* | Nonsense Mutation (SNP) | VAF 8/41 reads (20%) | catalogued as COSV52506767; called by mutect2, varscan2
- AMFR | c.1561C>T p.P521S | Missense Mutation (SNP) | VAF 49/310 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1207778284, COSV51920505; called by muse, varscan2
- AMPD3 | c.943G>A p.D315N (on ENST00000396553 / NM_001025389.2; = p.D324N on NM_000480.3) | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV67330435; called by muse, mutect2, varscan2
- ANGPT2 | c.715G>A p.V239M | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.104); catalogued as COSV57335356; called by mutect2, varscan2
- ANK3 | c.11272G>A p.E3758K | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.115); catalogued as COSV55050686; called by mutect2, varscan2
- ANKEF1 | c.587G>A p.G196E | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65692167; called by muse, varscan2
- ANKIB1 | c.400G>T p.E134* | Nonsense Mutation (SNP) | VAF 14/76 reads (18%) | catalogued as COSV56060039, COSV99730082; called by muse, mutect2, varscan2
- ANKRD30A | c.1180G>A p.E394K (on ENST00000611781; = p.E338K on NM_052997.2) | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.292); catalogued as COSV64607676; called by muse, varscan2
- ANKRD54 | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53236023; called by mutect2, varscan2
- ANLN | c.2886C>T p.V962= | Splice Region (SNP) | VAF 11/124 reads (9%) | catalogued as COSV56074903; called by muse, mutect2
- ANO2 | c.1471C>T p.R491* (on ENST00000356134 / NM_001278597.3; = p.R495* on NM_001278596.3) | Nonsense Mutation (SNP) | VAF 18/74 reads (24%) | catalogued as rs750547819, COSV59007007; called by mutect2, varscan2
- AOAH | c.1469G>C p.S490T | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as COSV51738184; called by muse, mutect2
- APOB | c.11359C>G p.P3787A | Missense Mutation (SNP) | VAF 47/361 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51929982; called by muse, mutect2, varscan2
- APOB | c.8389G>A p.G2797R | Missense Mutation (SNP) | VAF 40/389 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51929999; called by muse, mutect2, varscan2
- APOB | c.5131G>A p.G1711R | Missense Mutation (SNP) | VAF 64/442 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV51930025; called by muse, varscan2
- APOL5 | c.128C>T p.P43L | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as rs1176639113, COSV50766567, COSV50766636; called by muse, mutect2, varscan2
- ARAP3 | c.406C>T p.P136S | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs770883137, COSV53349706; called by muse, varscan2
- ARGFX | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.235); catalogued as rs752404821, COSV57682040; called by mutect2, varscan2
- ARHGAP18 | c.1316T>G p.L439W | Missense Mutation (SNP) | VAF 13/157 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63763987; called by muse, mutect2
- ARHGAP24 | c.328C>A p.Q110K | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.163); catalogued as COSV67829557; called by mutect2, varscan2
- ARHGEF11 | c.3610G>A p.D1204N | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as rs1177418202, COSV59353224; called by muse, mutect2, varscan2
- ARID1B | c.2654G>A p.R885Q | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs988746594, COSV51656673; called by mutect2, varscan2
- ARMC4 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.636); catalogued as rs866196713, COSV59455677; called by mutect2, varscan2
- ARSF | c.1387G>A p.D463N | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.53); PolyPhen benign (0.036); catalogued as rs1383187608, COSV63839280, COSV63840772; called by mutect2, varscan2
- ASIC5 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.66); PolyPhen benign (0.006); catalogued as COSV72232517, COSV72232612; called by muse, mutect2, varscan2
- ASMTL | c.1634G>A p.S545N | Missense Mutation (SNP) | VAF 56/290 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.165); catalogued as COSV67243328; called by muse, mutect2, varscan2
- ASNS | c.1271G>A p.R424Q | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1283664547, COSV51551389, COSV51552115; called by muse, varscan2
- ASPH | c.2086C>T p.P696S | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775444911, COSV65243892; called by mutect2, varscan2
- ATL1 | c.971G>A p.G324D | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.88); PolyPhen benign (0.072); catalogued as rs368143849; called by mutect2, varscan2
- ATP10B | c.2971G>A p.V991I | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.173); catalogued as COSV59147590; called by muse, mutect2, varscan2
- ATP8A2 | c.1594G>A p.V532M | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV54945122; called by muse, mutect2, varscan2
- ATP8B4 | c.1915G>A p.D639N | Missense Mutation (SNP) | VAF 14/151 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.232); catalogued as COSV52712262; called by muse, mutect2
- ATXN3L | c.152G>A p.G51E | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.465); catalogued as rs1205752268, COSV66075498; called by muse, varscan2
- B3GALT1 | c.710C>T p.S237L | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59907874; called by mutect2, varscan2
- BAG6 | c.1609C>T p.P537S (on ENST00000676571; = p.P490S on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/199 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.706); catalogued as COSV52989294; called by muse, mutect2
- BARX2 | c.179C>T p.S60F | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs772560593, COSV99858719; called by muse, mutect2, varscan2
- BATF2 | c.559G>A p.G187R | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV57249692; called by muse, mutect2, varscan2
- BCAN | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.739); catalogued as COSV61256184; called by muse, mutect2, varscan2
- BCL11A | c.1723C>T p.P575S (on ENST00000335712 / NM_001365609.1; = p.P609S on NM_018014.4) | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.023); catalogued as COSV59627197; called by muse, mutect2, varscan2
- BCLAF3 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0.022); catalogued as COSV61413566; called by muse, mutect2, varscan2
- BDNF | c.583G>A p.G195S | Missense Mutation (SNP) | VAF 13/174 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59234133; called by muse, mutect2
- BEND4 | c.581C>T p.S194F | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.726); catalogued as COSV101549752, COSV101549764; called by muse, mutect2, varscan2
- BHMT2 | c.95C>T p.T32I | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as rs368668984; called by mutect2, varscan2
- BICC1 | c.1369C>T p.L457F | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.617); catalogued as COSV54062838; called by muse, mutect2
- BIRC2 | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV57160976; called by muse, mutect2, varscan2
- BPIFA1 | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62824168; called by muse, mutect2, varscan2
- BRAF | c.2203G>A p.E735K (on ENST00000288602 / NM_001374244.1; = p.E695K on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.189); catalogued as COSV56062510, COSV56125554, COSV56171407; called by muse, mutect2, varscan2
- BRINP2 | c.1297C>T p.P433S | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.142); catalogued as COSV64175547; called by mutect2, varscan2
- BRWD1 | c.329C>T p.S110F | Missense Mutation (SNP) | VAF 22/292 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV58122490, COSV58122822; called by muse, mutect2
- C12orf40 | c.1572G>A p.M524I | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV61129563; called by mutect2, varscan2
- C16orf71 | c.761G>A p.G254E | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs758436379, COSV73918483; called by mutect2, varscan2
- C19orf18 | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as rs150585544; called by mutect2, varscan2
- C19orf18 | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.066); catalogued as COSV100071713; called by muse, mutect2, varscan2
- C1GALT1C1L | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 85/507 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as COSV56751616; called by muse, mutect2, varscan2
- C1orf53 | c.420T>A p.N140K | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV66323427; called by muse, mutect2, varscan2
- C2CD6 | c.605G>A p.G202E | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762070438, COSV53792864; called by muse, mutect2, varscan2
- C2orf78 | c.1282C>T p.Q428* | Nonsense Mutation (SNP) | VAF 7/48 reads (15%) | catalogued as COSV68517054; called by mutect2, varscan2
- C6 | c.2611G>A p.E871K | Missense Mutation (SNP) | VAF 34/233 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs865941754, COSV54707096; called by muse, mutect2, varscan2
- C8A | c.1175G>A p.G392E | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.88); catalogued as COSV63483130; called by muse, mutect2, varscan2
- C8B | c.215C>T p.S72F | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV64777170; called by muse, mutect2, varscan2
- C9orf131 | c.1358G>A p.W453* | Nonsense Mutation (SNP) | VAF 13/58 reads (22%) | catalogued as COSV56610238; called by muse, mutect2, varscan2
- CA3 | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as rs557237110, COSV53409536, COSV53411192; called by mutect2, varscan2
- CACNA1B | c.3833C>T p.S1278F | Missense Mutation (SNP) | VAF 43/251 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.414); catalogued as COSV99498107; called by muse, mutect2, varscan2
- CACNA1E | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV62386290; called by muse, mutect2, varscan2
- CACNA1E | c.3725C>T p.A1242V | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.012); catalogued as COSV62387596; called by muse, mutect2, varscan2
- CACNA1E | c.6167C>T p.S2056F (on ENST00000367573 / NM_001205293.3; = p.S2013F on NM_000721.4) | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.271); catalogued as rs1558402407, COSV62387619; called by mutect2, varscan2
- CACNA2D3 | c.1842C>T p.F614= | Splice Region (SNP) | VAF 9/41 reads (22%) | catalogued as rs1005231866, COSV55527104, COSV99871678; called by mutect2, varscan2
- CACNA2D3 | c.1909G>A p.E637K | Missense Mutation (SNP) | VAF 25/206 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.18); catalogued as COSV55527112; called by muse, varscan2
- CACNA2D3 | c.3081G>A p.M1027I | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.109); catalogued as COSV55527131; called by mutect2, varscan2
- CADPS | c.3235C>T p.R1079W | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.798); catalogued as COSV51873529; called by mutect2, varscan2
- CALHM6 | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 30/174 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV100889452; called by muse, mutect2, varscan2
- CALHM6 | c.755C>T p.P252L | Missense Mutation (SNP) | VAF 30/169 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV63991474; called by mutect2, varscan2
- CAMK4 | c.1124G>A p.G375E | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs867091227, COSV56667777, COSV99998868; called by muse, mutect2, varscan2
- CAPG | c.136G>T p.D46Y | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV55706958; called by mutect2, varscan2
- CAPN6 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs1299590065, COSV60694410; called by mutect2, varscan2
- CARS1 | c.1894C>T p.H632Y | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.141); catalogued as rs1407054593, COSV53460939, COSV53462834; called by muse, mutect2, varscan2
- CASP5 | c.857T>G p.L286R | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52827661; called by muse, varscan2
- CATSPER2 | c.857C>T p.S286F | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58660523; called by muse, mutect2
- CATSPERD | c.652G>A p.G218R | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.027); catalogued as COSV67534284; called by muse, mutect2, varscan2
- CCDC141 | c.2314C>T p.H772Y | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.108); catalogued as COSV99836993; called by mutect2, varscan2
- CCDC54 | c.770G>A p.G257E | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.119); catalogued as COSV53758302; called by muse, mutect2, varscan2
- CCDC73 | c.2956C>T p.P986S | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV58797050; called by muse, mutect2, varscan2
- CCDC83 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.592); catalogued as COSV54700980; called by muse, mutect2, varscan2
- CCR7 | c.374G>A p.G125D | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV55849013; called by muse, mutect2, varscan2
- CD163L1 | c.2065G>A p.E689K | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.395); catalogued as COSV58013779; called by muse, mutect2, varscan2
- CD19 | c.160C>T p.R54W | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs758662669, COSV61188198; called by mutect2, varscan2
- CD22 | c.272G>A p.R91K | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); catalogued as COSV50050713; called by muse, mutect2, varscan2
- CD22 | c.1565G>A p.G522E | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as COSV99323366; called by muse, varscan2
- CD274 | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1243212672, COSV67501155; called by muse, mutect2, varscan2
- CDH13 | c.1544C>T p.S515F | Missense Mutation (SNP) | VAF 32/172 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs777041339, COSV51805487; called by muse, mutect2, varscan2
- CDH23 | c.697G>A p.D233N | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.969); catalogued as COSV54928952; called by muse, varscan2
- CDH26 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.051); catalogued as COSV54845053; called by mutect2, varscan2
- CDH26 | c.1085G>A p.R362K | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.03); catalogued as COSV54845073, COSV54856215; called by muse, mutect2, varscan2
- CDH4 | c.2680G>A p.D894N | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs760758114, COSV64648275, COSV64654891; called by mutect2, varscan2
- CDH7 | c.2245G>A p.D749N | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV59883694; called by muse, mutect2, varscan2
- CDKAL1 | c.1346C>T p.S449F | Missense Mutation (SNP) | VAF 40/686 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV51181609; called by muse, mutect2
- CDKL5 | c.2089C>T p.P697S | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV66110687; called by muse, mutect2, varscan2
- CDS1 | c.733C>T p.P245S | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV55687384; called by mutect2, varscan2
- CEACAM20 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 38/254 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as rs1312015733, COSV57601207; called by muse, mutect2, varscan2
- CEACAM20 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 42/198 reads (21%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as COSV57601217; called by muse, mutect2, varscan2
- CELF4 | c.463T>C p.F155L | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.176); catalogued as COSV58450297; called by muse, mutect2, varscan2
- CEP126 | c.1273G>A p.D425N | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.085); catalogued as COSV54823536; called by muse, mutect2, varscan2
- CFAP300 | c.745C>T p.P249S | Missense Mutation (SNP) | VAF 30/240 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as COSV71570701; called by muse, mutect2, varscan2
- CFAP44 | c.2776G>A p.E926K | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs753711694, COSV55610271; called by mutect2, varscan2
- CFAP57 | c.1156C>T p.P386S | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0.05); catalogued as rs1156375662, COSV63016679; called by muse, mutect2, varscan2
- CFAP61 | c.485G>A p.C162Y | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.351); catalogued as COSV55624174; called by muse, mutect2, varscan2
- CFAP92 | c.1148C>T p.A383V | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.046); catalogued as COSV54046845; called by mutect2, varscan2
- CFHR5 | c.1603G>A p.D535N | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs748341345, COSV56818591; called by muse, mutect2, varscan2
- CHAF1A | c.2596C>T p.P866S | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.493); catalogued as rs1293380219, COSV56671257; called by muse, mutect2, varscan2
- CHD6 | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58555622; called by mutect2, varscan2
- CHGB | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV66759717; called by muse, mutect2, varscan2
- CHIT1 | c.1397A>G p.N466S | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55145937; called by muse, mutect2, varscan2
- CHODL | c.382C>A p.Q128K | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.233); catalogued as COSV54731919; called by mutect2, varscan2
- CHRDL2 | c.1246G>A p.E416K (on ENST00000376332 / NM_001304415.1; = p.G434E on NM_015424.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV55222254, COSV55224974; called by muse, mutect2
- CHST1 | c.464G>A p.G155E | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.986); catalogued as COSV100346306, COSV99074266; called by muse, mutect2, varscan2
- CHST1 | c.463G>A p.G155R | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100346311, COSV99074267; called by mutect2, varscan2
- CIT | c.1502C>T p.S501F | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as rs1248895144, COSV55864703; called by muse, mutect2, varscan2
- CLCN1 | c.181-1G>A p.X61_splice | Splice Site (SNP) | VAF 29/158 reads (18%) | catalogued as COSV58368695; called by muse, mutect2, varscan2
- CLCN3 | c.245T>C p.V82A | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.101); catalogued as COSV61626733; called by muse, mutect2
- CLDN10 | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.464); catalogued as COSV65296963; called by mutect2, varscan2
- CLDN17 | c.359G>A p.G120E | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV54522619; called by muse, varscan2
- CLDN17 | c.338G>A p.R113K | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.02); catalogued as COSV54522181, COSV54522632; called by muse, varscan2
- CLVS2 | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV51560469; called by muse, mutect2
- CMKLR1 | c.323G>A p.G108E (on ENST00000312143 / NM_001142344.2; = p.G106E on NM_004072.3) | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56437300; called by mutect2, varscan2
- CMPK2 | c.1313T>C p.V438A | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.914); catalogued as COSV99878871; called by muse, mutect2, varscan2
- CMPK2 | c.1312G>A p.V438I | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as rs757300868, COSV99878875; called by mutect2, varscan2
- CMYA5 | c.7423G>A p.E2475K | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.702); catalogued as COSV71404959; called by muse, mutect2, varscan2
- CNR1 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV62986649; called by muse, varscan2
- CNTNAP2 | c.994A>T p.N332Y | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV62162592; called by mutect2, varscan2
- CNTNAP2 | c.3889G>A p.E1297K | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs777946931, COSV62162609; called by mutect2, varscan2
- COL12A1 | c.8512C>T p.P2838S | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.114); catalogued as COSV100486164; called by muse, mutect2, varscan2
- COL14A1 | c.2041G>A p.E681K | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV99919620; called by mutect2, varscan2
- COL17A1 | c.1594G>A p.G532R | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.181); catalogued as rs1215950667, COSV62226119; called by muse, mutect2, varscan2
- COL19A1 | c.2872C>T p.P958S | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59569372; called by mutect2, varscan2
- COL20A1 | c.3325G>A p.D1109N | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1042809022, COSV58914393; called by muse, mutect2, varscan2
- COL23A1 | c.522G>A p.R174= | Splice Region (SNP) | VAF 10/32 reads (31%) | catalogued as COSV66788809; called by muse, varscan2
- COL24A1 | c.2632C>T p.P878S | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.526); catalogued as COSV65304405; called by muse, mutect2, varscan2
- COL27A1 | c.1745C>T p.P582L | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV61924122, COSV61927952; called by mutect2, varscan2
- COL28A1 | c.1487G>A p.G496E | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68081409; called by muse, mutect2, varscan2
- COL2A1 | c.2788G>A p.G930S | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61529252; called by muse, mutect2, varscan2
- COL4A1 | c.3637G>A p.G1213S | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65423448; called by muse, mutect2, varscan2
- COL4A1 | c.3172G>A p.G1058S | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65423450; called by muse, mutect2
- COL4A1 | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV65423454; called by mutect2, varscan2
- COL4A5 | c.2678-1G>A p.X893_splice | Splice Site (SNP) | VAF 9/33 reads (27%) | catalogued as COSV60358947; called by muse, mutect2, varscan2
- COL4A5 | c.2855C>T p.P952L | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV60358956; called by muse, mutect2, varscan2
- COL4A6 | c.3431C>T p.P1144L | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57862482; called by muse, varscan2
- COL5A2 | c.2650C>T p.P884S | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.657); catalogued as COSV66408486; called by muse, mutect2, varscan2
- COL5A2 | c.1663G>A p.G555R | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100880497; called by muse, varscan2
- COL6A2 | c.2218G>A p.D740N | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.061); catalogued as rs1474632772, COSV56001822; called by mutect2, varscan2
- COL6A6 | c.4921C>T p.P1641S | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV62021594; called by muse, mutect2, varscan2
- COL9A1 | c.2083G>A p.D695N | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.975); catalogued as COSV57881589; called by muse, mutect2, varscan2
- COLEC12 | c.1499G>A p.G500E | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as COSV68369660; called by mutect2, varscan2
- COQ8A | c.56C>A p.T19N | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.086); catalogued as COSV100825713; called by mutect2, varscan2
- CPLANE2 | c.278C>T p.T93I | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV65056733; called by muse, mutect2, varscan2
- CPNE4 | c.1116+1G>A p.X372_splice | Splice Site (SNP) | VAF 6/45 reads (13%) | catalogued as COSV70192582; called by mutect2, varscan2
- CPQ | c.962G>A p.G321E | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as COSV55141918; called by muse, mutect2
- CREBBP | c.2092G>A p.A698T | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.046); catalogued as COSV99270573; called by muse, mutect2, varscan2
- CREG1 | c.433C>A p.P145T | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV65148499; called by mutect2, varscan2
- CRX | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.092); catalogued as COSV99704557; called by muse, mutect2, varscan2
- CSMD1 | c.7531G>A p.E2511K (on ENST00000520002; = p.E2510K on NM_033225.6) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs532940488, COSV59285142; called by mutect2, varscan2
- CSMD1 | c.2368G>A p.E790K (on ENST00000520002; = p.E789K on NM_033225.6) | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.737); catalogued as rs1167091984, COSV59303080; called by mutect2, varscan2
- CSMD1 | c.1124C>T p.S375L (on ENST00000520002; = p.S374L on NM_033225.6) | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs762593887, COSV68165271; called by mutect2, varscan2
- CSMD2 | c.3745G>A p.E1249K | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.62); PolyPhen benign (0.102); catalogued as COSV53897569, COSV53968476; called by mutect2, varscan2
- CTAGE1 | c.1466G>A p.G489D | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as COSV66942914; called by muse, mutect2, varscan2
- CTAGE6 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 27/206 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs17855659, COSV69916965; called by muse, varscan2
- CTNNA3 | c.715G>A p.D239N | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs1360112371, COSV65559601, COSV65567164; called by muse, mutect2
- CTNND1 | c.2342C>T p.T781I (on ENST00000399050 / NM_001085458.2; = p.T775I on NM_001331.3) | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100650146, COSV100650163; called by muse, mutect2
- CTNND1 | c.2524G>A p.E842K (on ENST00000399050 / NM_001085458.2; = p.E836K on NM_001331.3) | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.237); catalogued as COSV62382728, COSV62382958; called by mutect2, varscan2
- CUBN | c.3745C>T p.R1249C | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); catalogued as rs368224687; called by mutect2, varscan2
- CUX2 | c.4346C>T p.A1449V | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV55628248; called by muse, mutect2, varscan2
- CXorf66 | c.1028T>C p.I343T | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1282982230, COSV65169051; called by muse, varscan2
- CYP2S1 | c.199G>A p.V67M | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59505485; called by mutect2, varscan2
- CYP3A7 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 26/167 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.709); catalogued as COSV60481026; called by muse, mutect2, varscan2
- CYP4F11 | c.1186C>T p.P396S | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.014); catalogued as rs752351878, COSV56126350; called by mutect2, varscan2
- CYP4F3 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as rs1277304055, COSV55408338; called by mutect2, varscan2
- DAGLA | c.1972G>A p.G658R | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760283516, COSV57195068; called by mutect2, varscan2
- DCC | c.1295C>T p.P432L | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59094578; called by muse, mutect2, varscan2
- DCDC1 | c.2953G>A p.G985R (on ENST00000597505 / NM_001367979.1; = p.G92R on NM_020869.3) | Missense Mutation (SNP) | VAF 32/221 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60305019; called by muse, mutect2, varscan2
- DCLK1 | c.1625G>A p.G542D | Missense Mutation (SNP) | VAF 12/133 reads (9%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.954); catalogued as COSV55174599, COSV55205136; called by muse, mutect2
- DCX | c.917C>T p.S306F | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV57567652; called by muse, mutect2, varscan2
- DDI1 | c.337G>A p.G113R | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.018); catalogued as rs756239179, COSV56373146; called by mutect2, varscan2
- DDX3X | c.71C>A p.S24* | Nonsense Mutation (SNP) | VAF 34/102 reads (33%) | catalogued as COSV67863322; called by mutect2, varscan2
- DENND2C | c.2071G>A p.E691K (on ENST00000393274 / NM_001256404.2; = p.E634K on NM_198459.4) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67920805; called by mutect2, varscan2
- DES | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as COSV64659902; called by mutect2, varscan2
- DGKI | c.2909G>A p.G970D | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1382477123, COSV55943749; called by muse, mutect2
- DGUOK | c.526C>T p.L176F | Missense Mutation (SNP) | VAF 22/282 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.808); catalogued as COSV51203347; called by muse, mutect2
- DIPK2A | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.162); catalogued as COSV59856803; called by muse, mutect2
- DISP2 | c.250C>T p.P84S | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.003); catalogued as COSV51118361; called by mutect2, varscan2
- DLEC1 | c.2848G>A p.E950K | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.79); catalogued as COSV57297655; called by mutect2, varscan2
- DMBX1 | c.701C>T p.S234F | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.701); catalogued as COSV63601834; called by muse, mutect2, varscan2
- DMBX1 | c.1127G>A p.G376E | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1222751151, COSV63601837; called by mutect2, varscan2
- DMXL1 | c.7615C>T p.R2539* | Nonsense Mutation (SNP) | VAF 20/116 reads (17%) | catalogued as COSV60708259; called by muse, varscan2
- DNAH1 | c.5354T>A p.I1785N | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV70227613; called by muse, mutect2, varscan2
- DNAH10 | c.841G>A p.G281S (on ENST00000409039; = p.G220S on NM_207437.3) | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.169); catalogued as COSV68990807; called by muse, mutect2, varscan2
- DNAH10 | c.7943C>T p.S2648L (on ENST00000409039; = p.S2587L on NM_207437.3) | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs751315749, COSV68987215; called by mutect2, varscan2
- DNAH3 | c.10963C>T p.P3655S | Missense Mutation (SNP) | VAF 23/174 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.11); catalogued as COSV54512820; called by muse, mutect2, varscan2
- DNAH3 | c.8154G>A p.M2718I | Missense Mutation (SNP) | VAF 26/223 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.577); catalogued as COSV54512869; called by muse, mutect2, varscan2
- DNAH5 | c.10772G>A p.G3591E | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54214966, COSV99451847; called by muse, varscan2
- DNAH5 | c.1538G>A p.G513D | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs1239805651, COSV54215061, COSV99451621; called by muse, mutect2, varscan2
- DNAH7 | c.11707C>T p.L3903F | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56758050; called by muse, mutect2, varscan2
- DNAH8 | c.2758G>A p.G920R | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.168); catalogued as COSV59435342; called by muse, mutect2
- DNAH9 | c.10907G>A p.G3636E | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.344); catalogued as COSV52343085; called by mutect2, varscan2
- DNER | c.1866G>A p.W622* | Nonsense Mutation (SNP) | VAF 7/41 reads (17%) | catalogued as rs866256730, COSV59163145; called by muse, mutect2, varscan2
- DNMT3B | c.2518C>T p.R840* | Nonsense Mutation (SNP) | VAF 18/95 reads (19%) | catalogued as rs1182001726, COSV52416573; called by muse, mutect2, varscan2
- DOCK2 | c.4598G>A p.G1533E | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56951238; called by muse, mutect2, varscan2
- DPP10 | c.398C>T p.S133L | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59665314; called by mutect2, varscan2
- DPYD | c.2113C>T p.P705S | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64591830; called by mutect2, varscan2
- DRD2 | c.782G>A p.G261E | Missense Mutation (SNP) | VAF 21/173 reads (12%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.744); catalogued as COSV60756324; called by muse, mutect2, varscan2
- DSC1 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.089); catalogued as rs769698282, COSV57143460; called by mutect2, varscan2
- DSE | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs866075089, COSV59062855; called by muse, mutect2, varscan2
- DSG1 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.389); catalogued as rs866214983, COSV57134242; called by mutect2, varscan2
- DTNA | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV51997138; called by muse, mutect2, varscan2
- DYNAP | c.355C>T p.L119F (on ENST00000321600; = p.L93F on NM_173629.3) | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.258); catalogued as rs536303813, COSV58666191; called by mutect2, varscan2
- DYNC2H1 | c.10196T>C p.L3399S | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62090471; called by muse, varscan2
- EBF1 | c.1088T>A p.I363N | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100565990; called by muse, mutect2, varscan2
- EEF1A2 | c.154G>A p.G52R | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.312); catalogued as COSV53205471; called by muse, mutect2, varscan2
- EHF | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57667931; called by muse, mutect2, varscan2
- EHMT1 | c.2125C>T p.P709S | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1417694539, COSV58373089; called by muse, varscan2
- EIF4G2 | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV101150926; called by muse, varscan2
- EIF4G3 | c.3731A>T p.Q1244L | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.902); catalogued as COSV51678484; called by muse, mutect2, varscan2
- ELF5 | c.585G>A p.W195* (on ENST00000312319 / NM_198381.2; = p.W185* on NM_001422.4) | Nonsense Mutation (SNP) | VAF 10/90 reads (11%) | catalogued as COSV56628610; called by muse, mutect2, varscan2
- ELOVL2 | c.365C>T p.S122F | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV61154667; called by muse, mutect2, varscan2
- ENC1 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs1307300267, COSV56629138; called by muse, mutect2, varscan2
- EOMES | c.1966C>T p.P656S | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.057); catalogued as rs1559925577, COSV55411786; called by muse, mutect2, varscan2
- EP300 | c.1499C>T p.P500L | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.689); catalogued as COSV54329843; called by muse, mutect2, varscan2
- EPAS1 | c.1139G>A p.G380E | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV55385362; called by muse, mutect2, varscan2
- EPB41L2 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 55/310 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.524); catalogued as COSV61354242; called by muse, mutect2, varscan2
- EPHA4 | c.1226A>T p.Y409F | Missense Mutation (SNP) | VAF 37/248 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56029649; called by muse, varscan2
- EPHB2 | c.278C>T p.S93L | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as COSV65861323; called by mutect2, varscan2
- EPHB6 | c.1753G>A p.E585K | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.516); catalogued as COSV63891115; called by mutect2, varscan2
- EPO | c.522T>A p.N174K | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV53161234; called by muse, mutect2
- EPS8L1 | c.34A>C p.K12Q | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52381132; called by muse, mutect2, varscan2
- ESM1 | c.379G>A p.G127R | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67318443; called by muse, varscan2
- ESYT3 | c.2114G>A p.R705K | Missense Mutation (SNP) | VAF 59/344 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.428); catalogued as COSV67440603; called by muse, mutect2, varscan2
- EVPL | c.5770G>A p.G1924S | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56909061; called by muse, mutect2, varscan2
- EXOC3L1 | c.1383G>A p.R461= | Splice Region (SNP) | VAF 10/56 reads (18%) | catalogued as rs776251517, COSV52045615; called by mutect2, varscan2
- F13A1 | c.295C>T p.L99F | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV53556349, COSV99066067; called by muse, mutect2, varscan2
- FAM135B | c.1993G>A p.E665K | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV52715425; called by muse, varscan2
- FAM135B | c.825G>A p.E275= | Splice Region (SNP) | VAF 27/120 reads (23%) | catalogued as COSV52704189, COSV52715466; called by muse, mutect2, varscan2
- FAM83B | c.1234C>T p.P412S | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.073); catalogued as COSV60920792; called by muse, mutect2, varscan2
- FAM83F | c.589G>A p.D197N | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV60999832; called by muse, mutect2, varscan2
- FAM83H | c.2905C>T p.L969F | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV62027855; called by muse, mutect2, varscan2
- FAT3 | c.1853G>A p.G618E | Missense Mutation (SNP) | VAF 24/351 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53093571; called by muse, mutect2
- FAT3 | c.2303G>A p.G768E | Missense Mutation (SNP) | VAF 29/352 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53093587; called by muse, mutect2
- FAT4 | c.2460G>A p.M820I | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.871); catalogued as rs1476606649, COSV67883436; called by muse, mutect2, varscan2
- FBLIM1 | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.992); catalogued as COSV60029175; called by mutect2, varscan2
- FBLN1 | c.958C>T p.P320S | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.985); catalogued as COSV53045294; called by muse, mutect2, varscan2
- FBXO15 | c.1069C>T p.H357Y | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV54043988; called by mutect2, varscan2
- FBXO24 | c.1671G>A p.W557* (on ENST00000241071 / NM_033506.3; = p.W595* on NM_012172.5) | Nonsense Mutation (SNP) | VAF 8/54 reads (15%) | catalogued as COSV99575445; called by mutect2, varscan2
- FBXO24 | c.1672G>A p.E558K (on ENST00000241071 / NM_033506.3; = p.E596K on NM_012172.5) | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.138); catalogued as rs374181573, COSV53828765; called by mutect2, varscan2
- FER1L6 | c.4358G>A p.R1453Q | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs560213365, COSV67549074; called by muse, mutect2, varscan2
- FERMT1 | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144791466; called by mutect2, varscan2
- FHL3 | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.795); catalogued as COSV65952408; called by mutect2, varscan2
- FLG | c.6263G>A p.G2088E | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.949); catalogued as COSV64239459; called by muse, mutect2
- FLG | c.1619G>A p.G540E | Missense Mutation (SNP) | VAF 44/210 reads (21%) | SIFT tolerated (0.28); PolyPhen probably damaging (1); catalogued as COSV104425339, COSV64239463; called by muse, mutect2, varscan2
- FLG | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.557); catalogued as rs751519390, COSV64236489; called by muse, mutect2, varscan2
- FLG2 | c.4784G>A p.R1595Q | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT tolerated (0.59); catalogued as rs201802558, COSV101165639, COSV66167043; called by mutect2, varscan2
- FLNB | c.4894G>A p.E1632K | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.903); catalogued as rs768316224, COSV55872808; called by mutect2, varscan2
- FLRT3 | c.1771G>A p.E591K | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.573); catalogued as rs1424466266, COSV53965353; called by muse, mutect2, varscan2
- FLT3 | c.1850G>A p.G617E | Missense Mutation (SNP) | VAF 21/166 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54049176, COSV54063534; called by muse, mutect2, varscan2
- FMN2 | c.2537C>T p.S846F | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs867593720, COSV60425183; called by muse, mutect2, varscan2
- FMR1NB | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1034123999, COSV65071138; called by mutect2, varscan2
- FOLR3 | c.59G>A p.G20E | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV100281736, COSV61529970; called by muse, varscan2
- FREM1 | c.3678G>A p.M1226I | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV66521089; called by muse, mutect2, varscan2
- FREM1 | c.941C>T p.S314F | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as COSV63087233; called by muse, mutect2, varscan2
- FREM2 | c.5866G>A p.E1956K | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); catalogued as COSV54833377; called by mutect2, varscan2
- FRMD7 | c.1444C>T p.P482S | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV53745435; called by muse, mutect2, varscan2
- FRMPD1 | c.274G>A p.G92S | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1017054886, COSV63383038; called by muse, mutect2, varscan2
- FRMPD2 | c.472T>G p.C158G | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV59716667; called by muse, varscan2
- FSTL1 | c.379C>A p.Q127K | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as COSV55232778; called by mutect2, varscan2
- FXR1 | c.1558G>A p.G520R | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV59761990; called by muse, mutect2
- GABRB3 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 12/48 reads (25%) | PolyPhen benign (0); catalogued as COSV100165347; called by mutect2, varscan2
- GALP | c.315G>A p.M105I | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs867751771, COSV61999251; called by mutect2, varscan2
- GAP43 | c.323C>T p.P108L | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as rs1483101077, COSV59343265, COSV59343333; called by muse, mutect2, varscan2
- GBF1 | c.4979C>T p.S1660F (on ENST00000369983 / NM_001377137.1; = p.S1659F on NM_004193.3) | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs371117105, COSV64149632; called by mutect2, varscan2
- GDF3 | c.296C>T p.S99F | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs866471146, COSV61712086; called by muse, varscan2
- GFRA3 | c.670G>A p.D224N | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV51228201, COSV51230756; called by mutect2, varscan2
- GFRAL | c.476G>A p.G159E | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.73); catalogued as COSV61229621; called by muse, mutect2, varscan2
- GGCX | c.1303C>T p.R435W | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52087628; called by mutect2, varscan2
- GGH | c.284T>C p.F95S | Missense Mutation (SNP) | VAF 13/137 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52649859; called by muse, mutect2
- GIMAP8 | c.1879G>A p.E627K | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV56230646; called by muse, mutect2, varscan2
- GIT1 | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV56608436; called by mutect2, varscan2
- GJA4 | c.983C>T p.S328F | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as COSV60725134; called by muse, mutect2, varscan2
- GJB6 | c.691C>T p.H231Y | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs866050531, COSV53832173; called by muse, varscan2
- GLI2 | c.4180G>A p.E1394K (on ENST00000361492 / NM_001374353.1; = p.E1411K on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.048); catalogued as rs1489463100, COSV58038268, COSV58050782; called by muse, mutect2, varscan2
- GLI2 | c.4646G>A p.G1549E (on ENST00000361492 / NM_001374353.1; = p.G1566E on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58038281; called by muse, mutect2, varscan2
- GLIS3 | c.388A>T p.S130C | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV60926825; called by mutect2, varscan2
- GLRA1 | c.698-1G>A p.X233_splice | Splice Site (SNP) | VAF 6/45 reads (13%) | catalogued as COSV51009463; called by muse, mutect2, varscan2
- GMIP | c.1442C>T p.P481L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV52555247; called by muse, mutect2, varscan2
- GNPTAB | c.1177C>T p.H393Y | Missense Mutation (SNP) | VAF 50/211 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs756486285, COSV54778506; called by mutect2, varscan2
- GPR148 | c.700C>T p.L234F | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.913); catalogued as COSV59307950; called by muse, mutect2, varscan2
- GPR39 | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100258717; called by muse, mutect2, varscan2
- GPR50 | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.043); catalogued as rs867249936, COSV54437973, COSV54439238; called by mutect2, varscan2
- GPR83 | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.421); catalogued as COSV54717775; called by muse, mutect2, varscan2
- GRAMD2B | c.833C>T p.S278F | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.87); catalogued as COSV53506785; called by muse, mutect2, varscan2
- GREB1 | c.355C>T p.L119F | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1432882676, COSV52183879; called by muse, varscan2
- GRID2 | c.2479G>A p.D827N | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.847); catalogued as rs200927178, COSV56189674; called by muse, mutect2, varscan2
- GRWD1 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.101); catalogued as COSV53518219; called by muse, mutect2, varscan2
- GSS | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53812151; called by muse, mutect2, varscan2
- GTF3C1 | c.606C>T p.F202= | Splice Region (SNP) | VAF 18/76 reads (24%) | catalogued as COSV62240010; called by mutect2, varscan2
- GTPBP4 | c.476C>T p.S159F | Missense Mutation (SNP) | VAF 31/338 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV62550500; called by muse, mutect2
- GUCY1A2 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.197); catalogued as COSV56482760; called by mutect2, varscan2
- HAVCR2 | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 66/427 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57152264; called by muse, mutect2, varscan2
- HCFC1 | c.2213C>T p.T738I | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV60070907; called by muse, mutect2, varscan2
- HDAC9 | c.1292C>T p.S431L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs752484524, COSV67770493; called by mutect2, varscan2
- HDC | c.1582C>T p.R528C | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs375190332; called by mutect2, varscan2
- HERC2 | c.5002C>T p.R1668C | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV55313262; called by mutect2, varscan2
- HGD | c.1007G>A p.R336K | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.433); catalogued as COSV52197268; called by muse, mutect2, varscan2
- HHIPL2 | c.2020A>G p.S674G | Missense Mutation (SNP) | VAF 48/361 reads (13%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs760393511, COSV58564216; called by muse, mutect2, varscan2
- HIPK4 | c.596G>A p.W199* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as COSV52520080; called by mutect2, varscan2
- HIVEP1 | c.4160C>T p.S1387L | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101045728, COSV65100144; called by mutect2, varscan2
- HIVEP2 | c.4694C>T p.S1565F | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV50008009, COSV50011151; called by muse, mutect2, varscan2
- HNF4G | c.223G>A p.A75T (on ENST00000354370 / NM_001330561.2; = p.A122T on NM_004133.5) | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1325361498, COSV62966823; called by muse, mutect2, varscan2
- HNRNPCL1 | c.580G>A p.V194M | Missense Mutation (SNP) | VAF 20/252 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV58610686; called by muse, varscan2
- HTR2A | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.036); catalogued as COSV66326971; called by muse, mutect2, varscan2
- HTR3B | c.285G>A p.W95* | Nonsense Mutation (SNP) | VAF 12/89 reads (13%) | catalogued as rs267602701, COSV52743650, COSV52747767; called by muse, varscan2
- HTRA2 | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV51206701; called by muse, mutect2, varscan2
- HYDIN | c.12356C>T p.S4119F | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.466); catalogued as COSV66636817; called by muse, mutect2, varscan2
- IGF1 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 71/417 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); catalogued as COSV100191131, COSV61032120, COSV61035543; called by muse, mutect2, varscan2
- IGLV5-45 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.529); catalogued as rs1217257663; called by muse, mutect2, varscan2
- IGSF9 | c.1472C>T p.A491V (on ENST00000368094 / NM_001135050.2; = p.A475V on NM_020789.4) | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as COSV63639388; called by muse, mutect2, varscan2
- IGSF9B | c.3544C>T p.R1182W | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs765118637, COSV58063635; called by mutect2, varscan2
- IKZF3 | c.1336G>A p.G446R | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53100952; called by muse, mutect2, varscan2
- IL4R | c.1301C>T p.P434L | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV50140286; called by mutect2, varscan2
- INHBA | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.582); catalogued as rs1007889051, COSV54220533; called by mutect2, varscan2
- INO80 | c.2501C>T p.S834F | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.548); catalogued as rs531473781, COSV62737187; called by mutect2, varscan2
- INPP5D | c.1867G>A p.E623K (on ENST00000445964 / NM_001017915.3; = p.E622K on NM_005541.5) | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV64036286; called by muse, mutect2, varscan2
- INSL4 | c.364C>T p.P122S | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV53328932; called by muse, mutect2
- ITFG1 | c.743C>T p.T248I | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.029); catalogued as COSV57746319; called by muse, mutect2, varscan2
- ITGA4 | c.1277C>T p.S426L | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.173); catalogued as COSV51999064; called by mutect2, varscan2
- ITGA8 | c.2855G>A p.R952Q | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as rs768261688, COSV65225574; called by mutect2, varscan2
- ITGB3 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs543887885, COSV71383744; called by muse, mutect2, varscan2
- ITGB8 | c.676C>T p.H226Y | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV56006485; called by muse, mutect2, varscan2
- ITK | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 22/299 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0.297); catalogued as COSV101439584, COSV70061449; called by muse, mutect2
- ITK | c.608G>A p.S203N | Missense Mutation (SNP) | VAF 32/330 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs762058624, COSV70061458; called by muse, mutect2
- ITSN1 | c.1832G>A p.R611K | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.977); catalogued as COSV66082209; called by muse, mutect2, varscan2
- ITSN1 | c.3385C>T p.P1129S | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as COSV66082225; called by muse, varscan2
- IZUMO1 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55803613; called by muse, mutect2, varscan2
- JAG1 | c.2317G>A p.G773S | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs6032913, COSV54755292; called by muse, mutect2, varscan2
- JAK2 | c.2609C>T p.P870L | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV67597368; called by muse, varscan2
- JCAD | c.3229C>T p.P1077S | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs747166214, COSV64758789; called by mutect2, varscan2
- KAT8 | c.901T>C p.Y301H | Missense Mutation (SNP) | VAF 35/206 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV54895951; called by muse, mutect2, varscan2
- KCND3 | c.1654A>G p.K552E | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.081); catalogued as COSV56178086; called by muse, varscan2
- KCNH2 | c.1309G>A p.E437K | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.082); catalogued as COSV51131876; called by muse, mutect2, varscan2
- KCNJ5 | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775915273, COSV57964595; called by mutect2, varscan2
- KCNJ6 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 70/584 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV55711857, COSV99900450; called by muse, mutect2, varscan2
- KCNK5 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV63988747; called by muse, mutect2, varscan2
- KCNMA1 | c.3407G>A p.G1136E (on ENST00000286628 / NM_001161352.2; = p.G1078E on NM_002247.4) | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54238380; called by muse, varscan2
- KIAA1109 | c.11821C>T p.P3941S | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as COSV52667259; called by muse, mutect2, varscan2
- KIAA1210 | c.4001C>T p.S1334F | Missense Mutation (SNP) | VAF 49/163 reads (30%) | SIFT tolerated (0.62); PolyPhen benign (0.013); catalogued as COSV101274259; called by muse, mutect2, varscan2
- KIAA1210 | c.3505G>A p.E1169K | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); catalogued as COSV68176051, COSV68176411; called by muse, mutect2, varscan2
- KIAA1217 | c.1093A>C p.S365R | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100287435, COSV56814820; called by muse, mutect2, varscan2
- KIAA1217 | c.2317C>T p.P773S | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56814834; called by muse, mutect2, varscan2
- KL | c.2068C>T p.P690S | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66308355; called by muse, mutect2, varscan2
- KLHL1 | c.1135T>A p.L379M | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.971); catalogued as COSV64769559; called by muse, mutect2, varscan2
- KLHL31 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.031); catalogued as COSV63881662; called by mutect2, varscan2
- KLKB1 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV52994807; called by mutect2, varscan2
- KMT2A | c.7937C>T p.P2646L | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.895); catalogued as COSV100628966, COSV63284121; called by muse, mutect2
- KMT5B | c.1313C>T p.P438L | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58565050; called by muse, mutect2, varscan2
- KRT18 | c.684T>G p.I228M | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.961); catalogued as rs11551639, COSV66316028; called by muse, mutect2, varscan2
- KRT39 | c.1223C>T p.P408L | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.167); catalogued as rs1168056404, COSV62917004; called by muse, mutect2
- KRT76 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV60119689; called by mutect2, varscan2
- KRTAP10-7 | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59109867; called by muse, mutect2, varscan2
- KRTAP13-3 | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV61879701; called by muse, mutect2, varscan2
- LAMA2 | c.7118C>T p.S2373L | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as rs758887080, COSV70341720; ClinVar: uncertain significance / likely benign; called by mutect2, varscan2
- LAMB1 | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs142924307; called by mutect2, varscan2
- LAMB4 | c.2648G>A p.G883E | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as COSV52716506, COSV52733507; called by muse, mutect2, varscan2
- LAMP3 | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.031); catalogued as COSV55614106; called by muse, mutect2, varscan2
- LARS1 | c.1621A>C p.K541Q (on ENST00000394434 / NM_020117.11; = p.K514Q on NM_016460.3) | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as COSV50973599; called by muse, mutect2, varscan2
- LCE1E | c.146G>A p.G49E | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.057); catalogued as COSV64219681; called by muse, mutect2, varscan2
- LCE3B | c.218C>T p.S73F | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.663); catalogued as COSV59500568; called by muse, varscan2
- LCK | c.842C>T p.S281F | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs759646706, COSV60739481; called by muse, mutect2, varscan2
- LCT | c.5735G>A p.G1912E | Missense Mutation (SNP) | VAF 35/246 reads (14%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); catalogued as COSV51546545; called by muse, varscan2
- LELP1 | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1472112054, COSV64202378; called by muse, mutect2
- LIG3 | c.1933A>T p.M645L | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV52006756; called by muse, varscan2
- LILRA1 | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs141328341; called by mutect2, varscan2
- LILRA5 | c.856G>A p.D286N | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs866247645, COSV56642126; called by muse, mutect2, varscan2
- LILRA6 | c.908C>T p.S303F | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1357703940, COSV99557887; called by muse, mutect2
- LILRB1 | c.1856C>T p.S619F (on ENST00000427581; = p.S568F on NM_006669.6) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs780538983, COSV61116989; called by muse, mutect2, varscan2
- LILRB5 | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60256033; called by muse, varscan2
- LIMCH1 | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1182010024, COSV58279017; called by muse, mutect2
- LIPI | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as COSV60708652; called by muse, mutect2
- LIPK | c.193C>T p.P65S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68200834; called by muse, mutect2
- LMO2 | c.230G>A p.R77Q (on ENST00000395833 / NM_001142315.2; = p.R146Q on NM_005574.4) | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs1168626051, COSV57645838; called by muse, mutect2, varscan2
- LPA | c.3806C>T p.P1269L | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.976); catalogued as rs765360409, COSV100307223; called by mutect2, varscan2
- LPA | c.3805C>T p.P1269S | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as COSV100307226; called by muse, mutect2, varscan2
- LPIN1 | c.2224G>A p.E742K | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); catalogued as rs371993612; called by mutect2, varscan2
- LRGUK | c.1051T>C p.F351L | Missense Mutation (SNP) | VAF 12/191 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as COSV53636066; called by muse, mutect2
- LRP1B | c.10471G>A p.D3491N | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.805); catalogued as rs201065495, COSV67185308, COSV67189813; called by mutect2, varscan2
- LRRC1 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.037); catalogued as COSV63828536; called by muse, mutect2, varscan2
- LRRC17 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV50864354; called by muse, mutect2, varscan2
- LRRC2 | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.141); catalogued as COSV56125494; called by mutect2, varscan2
- LRRC66 | c.2315C>T p.P772L | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as rs755743387, COSV58632905, COSV58636046; called by mutect2, varscan2
- LRRC7 | c.4013C>T p.P1338L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.023); catalogued as COSV50434471; called by muse, mutect2
- LRRC73 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0.001); catalogued as rs1472512965, COSV99446895; called by mutect2, varscan2
- LRRTM1 | c.909G>A p.W303* | Nonsense Mutation (SNP) | VAF 4/35 reads (11%) | catalogued as COSV54439556, COSV54439824; called by mutect2, varscan2
- LUM | c.617C>T p.S206F | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); catalogued as COSV57127821, COSV57128719; called by muse, varscan2
- LY9 | c.1577G>A p.R526K | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.021); catalogued as COSV54433027; called by mutect2, varscan2
- MAB21L2 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1328813338, COSV58261285; called by mutect2, varscan2
- MAGEA11 | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV60754732; called by muse, mutect2, varscan2
- MAGEC1 | c.1063C>T p.Q355* | Nonsense Mutation (SNP) | VAF 13/94 reads (14%) | catalogued as COSV99595919; called by muse, mutect2, varscan2
- MAGEC1 | c.2048C>T p.P683L | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.013); catalogued as rs1453222738, COSV53570420; called by muse, mutect2, varscan2
- MAGEC2 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.408); catalogued as COSV55998695; called by mutect2, varscan2
- MAGEE1 | c.2551C>T p.H851Y | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.992); catalogued as COSV63909416; called by muse, mutect2
- MAGI2 | c.1639T>A p.Y547N | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.994); catalogued as COSV62643768; called by muse, mutect2, varscan2
- MAP1A | c.6616C>T p.P2206S | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as rs752880383, COSV55807479; called by mutect2, varscan2
- MAP3K11 | c.1643C>T p.S548F | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.682); catalogued as rs1369199782, COSV100482580, COSV58418698; called by mutect2, varscan2
- MAP3K3 | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV100675575; called by mutect2, varscan2
- MARCHF8 | c.38C>T p.S13F | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.133); catalogued as COSV100165860; called by muse, mutect2, varscan2
- MARF1 | c.4238G>A p.R1413Q | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.997); catalogued as rs765681821, COSV60021678; called by mutect2, varscan2
- MC3R | c.29T>C p.V10A | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV54763400; called by muse, mutect2, varscan2
- MCOLN3 | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.553); catalogued as COSV62013581; called by muse, mutect2, varscan2
- MCPH1 | c.2296C>T p.P766S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.861); catalogued as COSV60911906; called by mutect2, varscan2
- ME1 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.093); catalogued as COSV100866559; called by muse, varscan2
- MECOM | c.772C>T p.P258S (on ENST00000468789 / NM_001105078.4; = p.P446S on NM_004991.4) | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.996); catalogued as rs267599686, COSV52959125; called by muse, mutect2, varscan2
- MEIOB | c.1246G>A p.G416R | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV58053429; called by muse, mutect2, varscan2
- METTL9 | c.898G>A p.D300N | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51678674; called by mutect2, varscan2
- MGAT4C | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.084); catalogued as COSV59831507; called by muse, mutect2, varscan2
- MGLL | c.842C>T p.S281F (on ENST00000398104 / NM_001003794.2; = p.S291F on NM_007283.6) | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV54023933; called by muse, mutect2, varscan2
- MID2 | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV99464885; called by muse, mutect2, varscan2
- MID2 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs35716955, COSV99464890; called by muse, mutect2, varscan2
- MID2 | c.1619C>T p.P540L | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.225); catalogued as COSV53308075; called by muse, mutect2, varscan2
- MIP | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57788223; called by muse, mutect2, varscan2
- MKX | c.728G>A p.G243E | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65391852; called by muse, mutect2, varscan2
- MMP13 | c.220T>G p.F74V | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52823483; called by muse, mutect2
- MORC1 | c.1969C>T p.P657S | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV51717195; called by mutect2, varscan2
- MORC1 | c.1513G>A p.E505K | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.593); catalogued as COSV51713061, COSV51713217; called by muse, mutect2
- MOV10L1 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.847); catalogued as rs1464686822, COSV53169145; called by mutect2, varscan2
- MROH1 | c.1593G>A p.A531= | Splice Region (SNP) | VAF 8/74 reads (11%) | catalogued as rs1257333638; called by mutect2, varscan2
- MROH2B | c.932C>T p.P311L | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as rs1012688015, COSV68182649; called by muse, varscan2
- MROH5 | c.858G>A p.K286= | Splice Region (SNP) | VAF 7/21 reads (33%) | catalogued as rs1186247193, COSV71300939; called by muse, mutect2, varscan2
- MS4A1 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.036); catalogued as COSV61941918; called by muse, mutect2
- MS4A3 | c.329G>A p.G110E | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.376); catalogued as rs757226562, COSV53935581; called by muse, mutect2
- MSGN1 | c.143C>T p.S48F | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV55262669; called by mutect2, varscan2
- MSH4 | c.1607G>A p.G536E | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54199945, COSV54204363; called by muse, varscan2
- MT1H | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs748601665, COSV60090761; called by mutect2, varscan2
- MUC16 | c.40691G>A p.R13564K | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.65); catalogued as COSV66690917; called by muse, mutect2, varscan2
- MUC16 | c.24929G>A p.R8310K | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated, low confidence (0.98); PolyPhen benign (0.167); catalogued as COSV67456087; called by muse, mutect2
- MUC16 | c.19730C>T p.S6577L | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.322); catalogued as COSV67456105; called by mutect2, varscan2
- MUC16 | c.18962C>T p.P6321L | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV67456122; called by muse, mutect2, varscan2
- MUC16 | c.13306C>T p.P4436S | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.239); catalogued as COSV67456130; called by muse, mutect2, varscan2
- MUC16 | c.2981C>T p.A994V | Missense Mutation (SNP) | VAF 39/212 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.336); catalogued as COSV67456142; called by muse, mutect2, varscan2
- MUSK | c.934G>A p.D312N | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs376831940; called by muse, mutect2, varscan2
- MX2 | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.921); catalogued as rs1170842674, COSV58095013; called by mutect2, varscan2
- MXRA5 | c.7984C>T p.P2662S | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.076); catalogued as rs1287358606, COSV54230195; called by muse, varscan2
- MXRA5 | c.1307C>T p.S436F | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.741); catalogued as COSV54230214; called by muse, mutect2, varscan2
- MXRA5 | c.479G>A p.G160E | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866233220, COSV54222468; called by muse, varscan2
- MYBPC1 | c.1403G>A p.G468D (on ENST00000550270 / NM_206820.2; = p.G493D on NM_002465.4) | Missense Mutation (SNP) | VAF 24/167 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as COSV62252068; called by muse, mutect2, varscan2
- MYH4 | c.3547G>A p.E1183K | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756149036, COSV55115466; called by muse, mutect2, varscan2
- MYH7 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.309); catalogued as COSV62517836; called by muse, varscan2
- MYL1 | c.203C>T p.S68F | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.808); catalogued as COSV58973949; called by muse, mutect2, varscan2
- MYLK | c.5235G>A p.W1745* | Nonsense Mutation (SNP) | VAF 12/124 reads (10%) | catalogued as COSV60607750; called by muse, mutect2
- MYLK3 | c.1783G>A p.G595S | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67363390; called by muse, mutect2, varscan2
- MYO15A | c.4005G>A p.M1335I | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0.01); catalogued as COSV52754549; called by mutect2, varscan2
- MYO18B | c.3289G>A p.D1097N | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.465); catalogued as rs753957467, COSV59130072; called by mutect2, varscan2
- MYO1F | c.1421G>A p.G474E | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57793345; called by muse, mutect2, varscan2
- MYO5B | c.4225C>T p.L1409F | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as rs1016421905, COSV53215180; called by muse, mutect2
- MYO7A | c.6307C>T p.L2103F | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0.074); catalogued as rs1388758037, COSV60018232; called by muse, mutect2, varscan2
- MYO7B | c.5959G>A p.D1987N | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs200691709, COSV61442072; called by muse, varscan2
- MYT1L | c.628A>T p.K210* | Nonsense Mutation (SNP) | VAF 4/42 reads (10%) | catalogued as COSV67715221, COSV67727147; called by mutect2, varscan2
- NAA35 | c.793A>T p.M265L | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64484279, COSV64484384; called by mutect2, varscan2
- NALCN | c.4087G>A p.G1363R | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51926797; called by muse, mutect2, varscan2
- NCKAP5L | c.1717G>A p.E573K | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.419); catalogued as COSV60128440; called by mutect2, varscan2
- NCOA2 | c.1694C>T p.S565F | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV71763737; called by muse, mutect2, varscan2
- NDST3 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.247); catalogued as COSV56612462, COSV56616072; called by mutect2, varscan2
- NDUFAF1 | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 28/165 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1306297093, COSV52975019; called by muse, mutect2, varscan2
- NEB | c.6938G>A p.R2313Q | Missense Mutation (SNP) | VAF 28/182 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs753256671, COSV50827814; called by mutect2, varscan2
- NEB | c.4888G>A p.D1630N | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50918988; called by muse, mutect2
- NEB | c.2011G>A p.D671N | Missense Mutation (SNP) | VAF 16/193 reads (8%) | SIFT tolerated (0.77); PolyPhen probably damaging (0.997); catalogued as COSV50919706, COSV51459111; called by muse, mutect2
- NEUROD4 | c.751G>A p.G251S | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV54471094, COSV54472584; called by mutect2, varscan2
- NEUROD6 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.506); catalogued as COSV51770847, COSV51773858; called by muse, varscan2
- NEXMIF | c.4151G>A p.G1384E | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.414); catalogued as COSV50025078; called by muse, mutect2, varscan2
- NFXL1 | c.293G>A p.R98K | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61198471; called by muse, mutect2, varscan2
- NIBAN1 | c.1910G>A p.G637E | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768976459, COSV62284036; called by muse, mutect2, varscan2
- NIPSNAP2 | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs770231289, COSV59050728; called by mutect2, varscan2
- NLGN4X | c.2270C>T p.P757L | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.035); catalogued as rs758932180, COSV52017178, COSV99322406; called by muse, mutect2, varscan2
- NLGN4Y | c.1622C>T p.P541L | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as COSV59295088; called by muse, mutect2, varscan2
- NLRP1 | c.2846C>T p.P949L | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV52562412, COSV99036413; called by muse, mutect2, varscan2
- NLRP10 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as rs776567093, COSV60779598; called by mutect2, varscan2
- NLRP10 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.849); catalogued as rs1342311265, COSV60779606; called by muse, mutect2, varscan2
- NLRP13 | c.458G>A p.G153E | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV61620958; called by muse, mutect2, varscan2
- NLRP3 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV60222016; called by mutect2, varscan2
- NLRP5 | c.2609C>T p.S870F | Missense Mutation (SNP) | VAF 22/371 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV66762327, COSV66765072; called by muse, mutect2
- NMS | c.416C>T p.P139L | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as rs139519598; called by mutect2, varscan2
- NOD2 | c.1621C>T p.R541W | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as rs576658764, COSV56049355; ClinVar: uncertain significance; called by mutect2, varscan2
- NOM1 | c.1628C>T p.T543I | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV51979431; called by muse, mutect2, varscan2
- NOS1 | c.58C>T p.L20F | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV57609634; called by muse, mutect2, varscan2
- NOS3 | c.589G>A p.D197N | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs988809853, COSV52487746; called by mutect2, varscan2
- NOTCH3 | c.4724C>T p.P1575L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.041); catalogued as COSV54630977, COSV99656532; called by muse, mutect2, varscan2
- NOTCH4 | c.2725G>A p.D909N | Missense Mutation (SNP) | VAF 21/196 reads (11%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.974); catalogued as rs766521222, COSV66679180; called by mutect2, varscan2
- NPR3 | c.1007C>T p.S336F | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54086020; called by muse, mutect2, varscan2
- NR1D2 | c.140C>T p.S47F | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0.332); catalogued as COSV56991263; called by muse, mutect2
- NR2F1 | c.1210C>T p.R404C | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); catalogued as COSV59067969, COSV59070289; called by muse, varscan2
- NR5A2 | c.1315C>T p.R439C (on ENST00000367362 / NM_205860.3; = p.R393C on NM_003822.5) | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs762506535, COSV52645342; called by mutect2, varscan2
- NRAP | c.433A>G p.R145G | Missense Mutation (SNP) | VAF 26/213 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.194); catalogued as COSV63489461; called by muse, varscan2
- NRXN1 | c.4026A>C p.E1342D | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV60491560; called by muse, mutect2, varscan2
- NTM | c.896A>G p.N299S | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100868801; called by muse, mutect2, varscan2
- NUFIP2 | c.1061C>T p.P354L | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56602811; called by muse, mutect2, varscan2
- NUP98 | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 20/208 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61430470; called by muse, mutect2
- NUTM2F | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.208); catalogued as COSV53556273; called by muse, mutect2, varscan2
- NXPH1 | c.440G>A p.G147E | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68313096; called by muse, mutect2, varscan2
- NYAP2 | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56001928; called by muse, mutect2, varscan2
- OBSCN | c.7745C>T p.S2582F | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52758023; called by muse, mutect2
- OLFM3 | c.271G>A p.E91K (on ENST00000338858 / NM_001288821.1; = p.E71K on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV58797347; called by muse, mutect2, varscan2
- OMA1 | c.208T>A p.F70I | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.006); catalogued as COSV62254837; called by muse, mutect2, varscan2
- OPLAH | c.1172T>G p.V391G | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV70677613; called by muse, mutect2, varscan2
- OR10A4 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV65841826; called by muse, varscan2
- OR10H4 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as rs199816165, COSV59061504; called by mutect2, varscan2
- OR10J1 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV71128580; called by muse, mutect2, varscan2
- OR10T2 | c.588A>T p.K196N | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as COSV100554948, COSV57780721; called by mutect2, varscan2
- OR11H1 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV99421808; called by mutect2, varscan2
- OR13J1 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV65069506; called by muse, mutect2, varscan2
- OR2A12 | c.444G>A p.W148* | Nonsense Mutation (SNP) | VAF 18/171 reads (11%) | catalogued as COSV68821209, COSV68821390; called by muse, mutect2, varscan2
- OR2F1 | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as COSV101231314; called by muse, mutect2, varscan2
- OR2F1 | c.929G>A p.G310E | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV67331129; called by muse, mutect2, varscan2
- OR2T11 | c.269C>T p.S90F | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as COSV58185285; called by mutect2, varscan2
- OR2T6 | c.698G>A p.G233E | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV63215996; called by muse, mutect2, varscan2
- OR4A15 | c.385C>T p.H129Y | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.071); catalogued as COSV59034314; called by mutect2, varscan2
- OR4D2 | c.163C>T p.L55F | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV73459734; called by muse, mutect2, varscan2
- OR51A4 | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV66749251; called by mutect2, varscan2
- OR51E1 | c.604G>A p.G202S | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV67809586; called by muse, mutect2, varscan2
- OR51Q1 | c.197C>T p.S66F | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56178116; called by muse, mutect2, varscan2
- OR51T1 | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.751); catalogued as COSV59024578; called by mutect2, varscan2
- OR52A1 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0.009); catalogued as COSV61091903; called by mutect2, varscan2
- OR52M1 | c.669G>A p.M223I | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1371212709, COSV64171492; called by muse, varscan2
- OR52N2 | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57676470; called by mutect2, varscan2
- OR52R1 | c.910G>A p.D304N | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as rs752734603, COSV61887976; called by mutect2, varscan2
- OR5A1 | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs921174569, COSV100118253, COSV57376316; called by muse, mutect2, varscan2
- OR5C1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.344); catalogued as rs201425472; called by mutect2, varscan2
- OR5K3 | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.21); catalogued as COSV101051656; called by muse, mutect2, varscan2
- OR5T1 | c.236C>T p.S79L | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs866744236, COSV57302193; called by mutect2, varscan2
- OR6C4 | c.710C>T p.S237F | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.169); catalogued as COSV67792860; called by muse, mutect2, varscan2
- OR6Y1 | c.955G>A p.G319R | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as COSV56928877; called by muse, mutect2, varscan2
- OR8B12 | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.314); catalogued as rs770775228, COSV60911431; called by muse, mutect2, varscan2
- OR8D4 | c.286G>A p.G96R | Missense Mutation (SNP) | VAF 32/222 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV58429930; called by muse, varscan2
- OR9A4 | c.408G>A p.M136I | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.495); catalogued as COSV71885237; called by mutect2, varscan2
- OR9G4 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.073); catalogued as rs1172246341, COSV57248158; called by muse, varscan2
- OSM | c.43C>T p.L15F | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV53161039; called by muse, mutect2, varscan2
- OSMR | c.1007C>T p.P336L | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV57083313; called by mutect2, varscan2
- OTOA | c.2420T>G p.F807C (on ENST00000286149; = p.F793C on NM_144672.4) | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53751575; called by muse, varscan2
- OXGR1 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.108); catalogued as rs543269642, COSV53657111; called by mutect2, varscan2
- P2RX2 | c.688G>A p.E230K (on ENST00000343948 / NM_170683.4; = p.E158K on NM_012226.5) | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.239); catalogued as COSV57690588; called by mutect2, varscan2
- PAIP1 | c.1220C>T p.S407F | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs1179671189, COSV59085595; called by muse, mutect2, varscan2
- PANK4 | c.538C>T p.Q180* | Nonsense Mutation (SNP) | VAF 10/90 reads (11%) | catalogued as COSV65866302; called by muse, mutect2, varscan2
- PATJ | c.4814G>A p.G1605E | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57159103; called by muse, mutect2, varscan2
- PAX8 | c.655C>T p.P219S | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs931233049, COSV54507471; called by muse, mutect2, varscan2
- PBX3 | c.869G>A p.R290Q | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV60730917; called by mutect2, varscan2
- PCARE | c.435G>A p.W145* | Nonsense Mutation (SNP) | VAF 10/99 reads (10%) | catalogued as rs776459304, COSV59054043; called by mutect2, varscan2
- PCDH18 | c.2564C>T p.S855F | Missense Mutation (SNP) | VAF 10/137 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.38); catalogued as COSV61267347; called by muse, mutect2
- PCDHA11 | c.388C>T p.P130S | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.081); catalogued as COSV56489264; called by muse, mutect2, varscan2
- PCDHA13 | c.2333C>T p.P778L | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.013); catalogued as COSV56489287; called by muse, mutect2, varscan2
- PCDHA4 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.969); catalogued as COSV63540184; called by muse, mutect2, varscan2
- PCDHA5 | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV65350874; called by muse, mutect2, varscan2
- PCDHA6 | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV65350887; called by muse, mutect2, varscan2
- PCDHA7 | c.199G>A p.V67M | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.297); catalogued as COSV100971559; called by muse, mutect2, varscan2
- PCDHB15 | c.352C>T p.R118* | Nonsense Mutation (SNP) | VAF 14/90 reads (16%) | catalogued as rs782318242, COSV50858192; called by mutect2, varscan2
- PCDHB16 | c.1808C>T p.S603L | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1246116137, COSV53360177; called by mutect2, varscan2
- PCDHB2 | c.1020G>A p.M340I | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.005); catalogued as COSV50567415; called by muse, mutect2, varscan2
- PCDHB3 | c.14G>A p.G5E | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.818); catalogued as COSV50567457; called by mutect2, varscan2
- PCDHB5 | c.901C>T p.R301C | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.967); catalogued as COSV50648541; called by mutect2, varscan2
- PCDHB7 | c.1259C>T p.T420I | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.35); catalogued as rs1554280153, COSV50759757; called by mutect2, varscan2
- PCDHB9 | c.1259C>T p.T420I | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.159); catalogued as rs575441811, COSV53377144; called by muse, mutect2, varscan2
- PCDHGA4 | c.1409C>T p.S470L | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.017); catalogued as COSV53921844; called by mutect2, varscan2
- PCDHGA4 | c.1630A>C p.I544L | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.028); catalogued as COSV53921854; called by muse, mutect2, varscan2
- PCDHGB5 | c.770C>T p.P257L | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.104); catalogued as COSV53921907; called by muse, varscan2
- PCLO | c.2467C>T p.R823* | Nonsense Mutation (SNP) | VAF 28/172 reads (16%) | catalogued as COSV61614801; called by mutect2, varscan2
- PCLO | c.971C>T p.S324L | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.025); catalogued as rs1161437707, COSV61624558; called by mutect2, varscan2
- PCSK1 | c.1095C>T p.I365= | Splice Region (SNP) | VAF 14/110 reads (13%) | catalogued as COSV60738516; called by mutect2, varscan2
- PCSK2 | c.676G>A p.G226R | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52729332; called by muse, mutect2, varscan2
- PDE1C | c.1534G>A p.E512K | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as rs867261121, COSV100372832; called by muse, mutect2, varscan2
- PDE3A | c.2083C>T p.P695S | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV62970543; called by muse, mutect2, varscan2
- PDE4DIP | c.4018G>A p.E1340K | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.014); catalogued as rs782424563, COSV57686373; called by muse, mutect2, varscan2
- PDE6A | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV54925941; called by muse, varscan2
- PDILT | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.732); catalogued as rs1159297997, COSV56700561; called by muse, varscan2
- PGLYRP3 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV51949639; called by muse, mutect2, varscan2
- PGM5 | c.1588C>T p.P530S | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.146); catalogued as COSV67167238; called by muse, mutect2, varscan2
- PHLDB2 | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as COSV67309719; called by muse, mutect2, varscan2
- PIDD1 | c.1035C>A p.F345L | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs764617775, COSV61704796, COSV61707478; called by mutect2, varscan2
- PIK3R5 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as COSV52652098; called by muse, mutect2, varscan2
- PIKFYVE | c.5470C>T p.L1824F | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.155); catalogued as COSV52239111; called by muse, mutect2
- PIWIL1 | c.1505G>A p.R502Q | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.621); catalogued as rs778735608, COSV55345392; called by mutect2, varscan2
- PKHD1 | c.11380T>G p.S3794A | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV64385032; called by mutect2, varscan2
- PLA1A | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0.012); catalogued as COSV56331133; called by muse, mutect2
- PLA2G3 | c.1022C>T p.A341V | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as rs746074396, COSV53210988, COSV99311827; called by muse, mutect2, varscan2
- PLAAT5 | c.377G>A p.G126E | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.265); catalogued as COSV57136646; called by muse, mutect2
- PLCD1 | c.182C>T p.T61I | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as COSV58160167; called by muse, mutect2, varscan2
- PLCE1 | c.4484G>A p.R1495Q | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.882); catalogued as rs771124727, COSV53337446; called by mutect2, varscan2
- PLCL1 | c.1697G>A p.R566Q | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as rs370610240; called by mutect2, varscan2
- PLEKHA4 | c.1976C>T p.T659I | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.07); catalogued as COSV54362126; called by mutect2, varscan2
- PLG | c.1393C>T p.P465S | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs757219403, COSV99804805, COSV99805148; called by muse, mutect2, varscan2
- PLIN4 | c.2050G>A p.D684N (on ENST00000301286; = p.D699N on NM_001367868.2) | Missense Mutation (SNP) | VAF 17/183 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.247); catalogued as COSV56689154; called by muse, mutect2, varscan2
- PLPP2 | c.202C>T p.L68F | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.359); catalogued as COSV54120014, COSV99514511; called by muse, varscan2
- PLS1 | c.1541G>A p.G514D | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV61833339; called by muse, mutect2, varscan2
- PMFBP1 | c.653G>A p.G218D | Missense Mutation (SNP) | VAF 15/150 reads (10%) | SIFT tolerated (0.16); PolyPhen probably damaging (1); catalogued as rs1482713463, COSV52822330; called by muse, mutect2, varscan2
- PNLDC1 | c.1060G>A p.D354N | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99277611; called by mutect2, varscan2
- PNLIPRP1 | c.718G>A p.G240S | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV62611302; called by muse, mutect2, varscan2
- POLR1B | c.1637C>T p.P546L | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV54494717; called by muse, mutect2, varscan2
- POU2F3 | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV52793116; called by muse, mutect2, varscan2
- PPIP5K1 | c.3697C>T p.L1233F (on ENST00000396923; = p.L1208F on NM_014659.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.084); catalogued as COSV55807484; called by mutect2, varscan2
- PPP4R3A | c.2305C>T p.P769S (on ENST00000554943 / NM_001366432.1; = p.P756S on NM_001284280.1) | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.02); catalogued as COSV61504074; called by muse, varscan2
- PRAMEF2 | c.353G>A p.G118E | Missense Mutation (SNP) | VAF 52/259 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as COSV53574129; called by muse, mutect2, varscan2
- PRAMEF2 | c.1169C>T p.S390F | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs776428150, COSV53574151; called by mutect2, varscan2
- PRAMEF5 | c.419G>A p.R140K | Missense Mutation (SNP) | VAF 66/220 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.149); catalogued as rs1306268322; called by muse, varscan2
- PRB2 | c.545G>A p.G182E | Missense Mutation (SNP) | VAF 27/218 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as rs777981321, COSV66982697; called by muse, varscan2
- PRDM5 | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 13/146 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV53358211; called by muse, mutect2
- PRDM9 | c.1475G>A p.R492K | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.046); catalogued as COSV57004487; called by muse, mutect2, varscan2
- PRELID3B | c.538G>A p.G180R | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV54812460; called by muse, mutect2, varscan2
- PRKCQ | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.74); PolyPhen probably damaging (0.996); catalogued as rs994508173, COSV54109108, COSV54112815; called by mutect2, varscan2
- PRMT8 | c.500G>A p.G167D | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1203557284, COSV54212997; called by muse, mutect2, varscan2
- PROSER3 | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV56552980; called by muse, mutect2, varscan2
- PRPF6 | c.2772G>T p.K924N | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.209); catalogued as rs755367167, COSV53868159; called by mutect2, varscan2
- PRR16 | c.872C>T p.P291L (on ENST00000407149 / NM_001300783.2; = p.P268L on NM_016644.2) | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65397148; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1703C>T p.S568F (on ENST00000352766; = p.S489F on NM_181334.5) | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.425); catalogued as COSV61232467; called by mutect2, varscan2
- PRR5L | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.051); catalogued as COSV61120826; called by muse, mutect2, varscan2
- PRX | c.2944G>A p.E982K | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.521); catalogued as COSV52528817; called by muse, mutect2, varscan2
- PSG11 | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.05); catalogued as COSV60454478, COSV60455306; called by muse, mutect2, varscan2
- PSG5 | c.559C>T p.L187F | Missense Mutation (SNP) | VAF 20/334 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV61653940; called by muse, mutect2
- PSG6 | c.1181C>T p.S394F | Missense Mutation (SNP) | VAF 38/225 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as COSV51831674; called by muse, mutect2, varscan2
- PSG8 | c.602C>T p.T201I | Missense Mutation (SNP) | VAF 18/261 reads (7%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.517); catalogued as rs1410645787, COSV60610689; called by muse, mutect2
- PTGFRN | c.932C>T p.P311L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.013); catalogued as rs1483405024, COSV67798112; called by muse, mutect2, varscan2
- PTPRD | c.4253G>C p.G1418A | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61936755, COSV61986973; called by muse, mutect2, varscan2
- PTPRD | c.733C>T p.H245Y | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.021); catalogued as COSV61936769; called by mutect2, varscan2
- PTPRN2 | c.2935G>A p.E979K | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67030743; called by muse, varscan2
- PTPRN2 | c.380+1G>A p.X127_splice | Splice Site (SNP) | VAF 12/78 reads (15%) | catalogued as COSV67030748; called by muse, varscan2
- PTPRO | c.3211G>A p.E1071K (on ENST00000281171 / NM_030667.3; = p.E1043K on NM_002848.4) | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.057); catalogued as COSV55506401; called by muse, mutect2, varscan2
- PTPRT | c.3323G>A p.G1108E | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs750916964, COSV61968738, COSV61972440; called by muse, mutect2, varscan2
- PTPRT | c.1651C>T p.H551Y | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs724159839, COSV61972464; called by mutect2, varscan2
- PTPRZ1 | c.344G>A p.G115E | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66433839; called by muse, mutect2, varscan2
- R3HCC1L | c.205C>T p.R69* | Nonsense Mutation (SNP) | VAF 14/132 reads (11%) | catalogued as rs779291841, COSV54400194; called by mutect2, varscan2
- RAB3IP | c.1195G>A p.G399S (on ENST00000550536 / NM_175623.4; = p.G383S on NM_022456.5) | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.265); catalogued as COSV56082656; called by muse, mutect2
- RAI2 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.77); PolyPhen benign (0.083); catalogued as rs751935740, COSV58963706; called by muse, mutect2, varscan2
- RAPGEF6 | c.2998C>T p.L1000F | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.836); catalogued as COSV57243385; called by muse, mutect2, varscan2
- RASL11A | c.697C>T p.P233S | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54079881; called by muse, mutect2, varscan2
- RBFOX1 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV60952754; called by muse, varscan2
- RBM25 | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.039); catalogued as rs769862511, COSV56199223; called by mutect2, varscan2
- RBM43 | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as COSV58878440; called by muse, mutect2, varscan2
- RBP1 | c.272G>A p.G91E (on ENST00000619087 / NM_001365940.2; = p.G153E on NM_002899.5) | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.05); catalogued as COSV51676094; called by mutect2, varscan2
- RELN | c.4805C>T p.S1602F | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1370209776, COSV58994102; called by muse, mutect2, varscan2
- RELN | c.3338G>A p.G1113E | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs751103966, COSV100634045; called by mutect2, varscan2
- REN | c.761G>A p.G254E | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as COSV65817558, COSV65817839; called by muse, mutect2, varscan2
- RERG | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 25/210 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.161); catalogued as rs1234565536, COSV57000650; called by mutect2, varscan2
- RERGL | c.556G>A p.G186R | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV57461359; called by mutect2, varscan2
- RGS11 | c.1276G>A p.E426K (on ENST00000397770 / NM_183337.3; = p.E405K on NM_003834.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV51451936; called by mutect2, varscan2
- RHAG | c.295G>A p.G99R | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57703712; called by muse, mutect2, varscan2
- RIMBP2 | c.2864G>A p.R955Q | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs771054251, COSV55468798; called by mutect2, varscan2
- RIMS2 | c.1940G>A p.R647K (on ENST00000666250 / NM_001348490.2; = p.R455K on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV51668009; called by muse, mutect2, varscan2
- RIOK2 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 25/154 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374216082; called by mutect2, varscan2
- RIT2 | c.88G>A p.G30R | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56296943; called by muse, mutect2, varscan2
- RNF123 | c.629C>T p.S210F | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.505); catalogued as COSV59685750; called by mutect2, varscan2
- RNF133 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs113296018; called by mutect2, varscan2
- RNF17 | c.2134G>A p.E712K | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV55037245; called by muse, mutect2, varscan2
- RNF17 | c.4598C>T p.P1533L | Missense Mutation (SNP) | VAF 11/172 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55037264; called by muse, mutect2
- RNF19B | c.1435C>T p.P479S | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs759442240, COSV52387221; called by mutect2, varscan2
- RNF207 | c.1549C>T p.L517F | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs780573668, COSV65007376; called by muse, mutect2, varscan2
- ROR1 | c.2452C>T p.P818S | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1423421156, COSV64285854; called by muse, varscan2
- ROR2 | c.2221G>A p.D741N | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65217859; called by mutect2, varscan2
- RP1L1 | c.4144G>A p.E1382K | Missense Mutation (SNP) | VAF 22/272 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV66753461; called by muse, mutect2
- RPE65 | c.223G>A p.G75R | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267598701, COSV52014811; called by muse, mutect2, varscan2
- RPH3A | c.1318G>A p.A440T (on ENST00000389385 / NM_001143854.2; = p.A436T on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV66990495; called by muse, varscan2
- RPS6KC1 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65298225; called by mutect2, varscan2
- RPUSD2 | c.1334C>T p.P445L | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV59765147; called by muse, mutect2, varscan2
- RTCA | c.1055A>T p.Y352F | Missense Mutation (SNP) | VAF 57/357 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV53119995, COSV53120122; called by muse, mutect2, varscan2
- RTCB | c.1144C>T p.P382S | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.904); catalogued as COSV53277874; called by muse, mutect2, varscan2
- RTL6 | c.311C>T p.P104L | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.943); catalogued as COSV100373806; called by muse, mutect2, varscan2
- RUNX1T1 | c.703G>A p.D235N (on ENST00000265814 / NM_001198628.1; = p.D208N on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.26); catalogued as COSV56137209; called by mutect2, varscan2
- RYR3 | c.5872G>A p.E1958K | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.014); catalogued as rs768387060, COSV66783192; ClinVar: uncertain significance; called by mutect2, varscan2
- SAA2-SAA4 | c.484C>T p.Q162* | Nonsense Mutation (SNP) | VAF 7/39 reads (18%) | catalogued as COSV53447946; called by mutect2, varscan2
- SACS | c.11362C>T p.R3788C | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs931398747, COSV66537203; called by mutect2, varscan2
- SAMD3 | c.947G>A p.R316K | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV63714757; called by muse, mutect2, varscan2
- SAMD4A | c.1654C>T p.L552F | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.462); catalogued as COSV51878738; called by muse, mutect2, varscan2
- SAMD7 | c.1219G>A p.D407N | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.046); catalogued as COSV59417850; called by mutect2, varscan2
- SAXO2 | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 23/199 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775928983, COSV59753690; called by muse, mutect2, varscan2
- SCN11A | c.5261G>A p.G1754D | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV100181549, COSV56568086; called by mutect2, varscan2
- SCN11A | c.2761G>A p.E921K | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.022); catalogued as COSV56568094; called by muse, varscan2
- SCN11A | c.542G>A p.R181K | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.61); catalogued as COSV100182930, COSV56568124; called by muse, mutect2, varscan2
- SCN2A | c.1628G>A p.G543E | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV51836882; called by muse, mutect2, varscan2
- SEMA3E | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV57084466, COSV57094729; called by muse, varscan2
- SERPINB13 | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54028036; called by mutect2, varscan2
- SERPINI2 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as rs777862293, COSV52985286; called by muse, mutect2, varscan2
- SEZ6L | c.1525C>T p.H509Y | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50660371; called by mutect2, varscan2
- SGSM1 | c.2753C>T p.S918F (on ENST00000400359 / NM_001039948.4; = p.S857F on NM_133454.3) | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.914); catalogued as COSV100771872; called by mutect2, varscan2
- SGSM1 | c.3298T>A p.Y1100N (on ENST00000400359 / NM_001039948.4; = p.Y1039N on NM_133454.3) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68509525; called by mutect2, varscan2
- SH2D3C | c.146C>T p.T49I | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV100137081; called by muse, mutect2, varscan2
- SH3RF2 | c.1979C>T p.P660L | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.024); catalogued as COSV63038157; called by muse, varscan2
- SHROOM3 | c.3796G>A p.D1266N | Missense Mutation (SNP) | VAF 35/225 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as rs751714829, COSV56026284; called by muse, mutect2, varscan2
- SI | c.1827G>A p.W609* | Nonsense Mutation (SNP) | VAF 10/76 reads (13%) | catalogued as rs755917203, COSV52271950; called by mutect2, varscan2
- SIGLEC9 | c.518G>A p.G173E | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV51583429; called by mutect2, varscan2
- SLC10A4 | c.1073G>A p.G358E | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV56718386; called by muse, mutect2, varscan2
- SLC12A3 | c.2335G>A p.G779R | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1364572210, COSV52633520; called by muse, varscan2
- SLC13A5 | c.449C>T p.P150L | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53422372; called by mutect2, varscan2
- SLC22A11 | c.809C>T p.S270F | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57252443; called by muse, mutect2, varscan2
- SLC26A7 | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52589719, COSV52600870; called by muse, varscan2
- SLC26A9 | c.1107G>A p.M369I | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV100536947, COSV61601719; called by mutect2, varscan2
- SLC28A1 | c.1541G>A p.G514E | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54477756; called by muse, mutect2, varscan2
- SLC2A12 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as rs779184200, COSV51597479; called by mutect2, varscan2
- SLC2A3 | c.65T>C p.F22S | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs781561134, COSV50001588; called by muse, varscan2
- SLC2A6 | c.1502G>A p.G501E | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as COSV52469386; called by muse, varscan2
- SLC34A2 | c.1620C>G p.I540M | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV101158455, COSV65941132; called by muse, mutect2, varscan2
- SLC38A10 | c.1877C>T p.A626V | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.395); catalogued as rs748152016, COSV55844243; called by mutect2, varscan2
- SLC4A3 | c.1852G>A p.G618S | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.401); catalogued as COSV56092650; called by muse, varscan2
- SLC4A8 | c.883C>T p.P295S | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60650252; called by muse, mutect2, varscan2
698 further variants in this file (169 protein-altering or splice-affecting, 506 silent, 23 other) are not listed here.
